Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3599, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3599-01A (Primary Tumor).

Diagnosis/diagnoses:

Resected (rectosigmoid) colon shows a rectal carcinoma characterized histologically as a moderately differentiated, partly mucinous colorectal adenocarcinoma, measuring 2 cm in diameter at the widest point. Invasive tumor spread to the level of the muscularis propria. Oral and aboral resection margin and the isolated intestinal and colon section under examination are all tumor-free.

Seven mesocolic and periproctic lymph nodes are tumor-free and with non-characteristic reactive lesions.

Stage of tumor: pT2 pN0 (0/7) L0 V0; G2

Follow-up report:

A further lymph node preparation was retrospectively examined after special fixation.

Five further very small periproctic and mesocolic lymph nodes were identified here. The lymph nodes are histologically tumor-free.

Lymph node status pN0 (0/12).

Source: NCI Genomic Data Commons file 0e4cf3cf-d970-4d1a-b493-de8f6cf051f3 (TCGA-AG-3599.78A3A434-E498-493D-BB8E-F6BD53CD3F62.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).